Gene-level copy-number profile of tumor specimen TCGA-IQ-A61K-01A from TCGA case TCGA-IQ-A61K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 70.4 years (25,697 days).
Specimen TCGA-IQ-A61K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.97ef0970-c171-4848-a954-1b94663ec4c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-A61K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33310d97-f7e2-4639-9cc4-0f297a31a2e8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,562; copy number 3: 31,504; copy number 4: 19,641; copy number 5: 328; copy number 6: 2,004; copy number 7: 879; copy number 8: 613; copy number 9: 12; copy number 10: 125; copy number 11: 4; copy number 13: 14; copy number 14: 77; copy number 16: 8; copy number 17: 31; copy number 21: 11; copy number 26: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-A61K-01A-11D-A30D-01): tumor purity 0.61, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,779 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:80,162,428–86,106,155, 88 genes, copy number 14–21 (within-gene range 6–21) (broad region; genes not listed).
- chr2:142,877,657–143,055,833, 2 genes, copy number 10 (within-gene range 4–10): KYNU, SFXN4P1.
- chr2:143,093,056–143,101,355, 9 genes, copy number 10: MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5.
- chr8:46,549,089–51,015,165, 76 genes, copy number 8–17 (broad region; genes not listed).
- chr10:42,979,017–44,310,237, 40 genes, copy number 8: LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1, SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3.
- chr10:48,664,199–49,667,942, 22 genes, copy number 7 (within-gene range 2–8): AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4, FAM170B-AS1, FAM170B, TMEM273, C10orf71-AS1, C10orf71, DRGX, AL138760.1, ERCC6, HMGB1P50, CHAT, SLC18A3.
- chr10:50,799,409–53,766,614, 24 genes, copy number 7–9: A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:56,357,227–64,826,579, 80 genes, copy number 8–10 (broad region; genes not listed).
- chr10:90,622,143–92,574,096, 38 genes, copy number 7 (within-gene range 2–7): AL390862.1, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1, CPEB3, AL365398.1, SDHCP2, EIF4A1P8, AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12, MARK2P9, AL161652.1, IDE.
- chr10:108,296,099–111,498,941, 45 genes, copy number 7: PTGES3P5, AL353740.1, LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5, RPL7P35, SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1, BTBD7P2, AC021035.1, RPS6P15.
- chr11:34,570,876–35,420,063, 13 genes, copy number 16–26 (within-gene range 5–26): LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1.
- chr11:37,702,125–38,014,141, 4 genes, copy number 11: AC061997.1, RPL7AP56, LINC02760, AC103798.1.
- chr13:72,727,749–73,661,891, 14 genes, copy number 13 (within-gene range 2–13): BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr16:32,278,866–90,222,851, 1,324 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
